Somatic mutation profile of tumor specimen TCGA-06-2564-01A (aliquot TCGA-06-2564-01A-01D-1494-08) from TCGA case TCGA-06-2564, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.5 years (18,435 days).
Specimen TCGA-06-2564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbfacc6d-897c-4dd0-a406-4b30219585a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2564-10A (Blood Derived Normal), aliquot TCGA-06-2564-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8620a956-df26-43be-a00a-be75192167b6

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF2 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 54/237 reads (23%) | catalogued as COSV55182566; called by muse, mutect2, varscan2
- AGO3 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV55793090; called by muse, mutect2, varscan2
- ATP2B2 | c.2401C>T p.R801W (on ENST00000352432; = p.R767W on NM_001683.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866132370, COSV59488095, COSV59495231; called by muse, mutect2
- BPNT2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs758965196, COSV52907247; called by muse, mutect2, varscan2
- C15orf48 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs143173357, COSV60223381; called by muse, mutect2, varscan2
- CACNA1I | c.5887G>T p.E1963* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV60806756; called by muse, mutect2, varscan2
- CELA3A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.74); PolyPhen probably damaging (1); catalogued as rs533686702, COSV51583198; called by muse, mutect2, varscan2
- COL4A4 | c.5029C>T p.R1677C | Missense Mutation (SNP) | VAF 372/993 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759631057, CM074108, COSV61629349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSDC2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53447746; called by muse, mutect2
- CSE1L | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1360257614, COSV53701609; called by muse, mutect2, varscan2
- DDX49 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV53230311; called by muse, mutect2
- ENO2 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV50388193; called by muse, mutect2, varscan2
- EPB41 | c.1021G>A p.D341N (on ENST00000343067 / NM_001166005.2; = p.D132N on NM_004437.4) | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58045806; called by muse, mutect2, varscan2
- EPHA10 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT tolerated (0.55); PolyPhen probably damaging (1); catalogued as rs749221168, COSV57623705; called by muse, mutect2, varscan2
- ERCC6L2 | c.767T>G p.L256* | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | catalogued as COSV56629979; called by muse, mutect2, varscan2
- FBN3 | c.6322C>T p.R2108C | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs753202834, COSV54459276; called by muse, mutect2, varscan2
- FLG | c.8507G>A p.S2836N | Missense Mutation (SNP) | VAF 229/1667 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs777731067, COSV64240932; called by muse, mutect2, varscan2
- FRK | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs142072444; called by muse, mutect2, varscan2
- FSTL4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765016023, COSV54768190, COSV54769302; called by muse, mutect2, varscan2
- GSDME | c.1257G>A p.L419= | Splice Region (SNP) | VAF 60/315 reads (19%) | catalogued as COSV61651520; called by muse, mutect2, varscan2
- KMT2D | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV56434482, COSV99985547; called by muse, mutect2, varscan2
- KRTAP10-4 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.509); catalogued as rs201736033; called by muse, mutect2
- LRRIQ1 | c.4345del p.E1449Nfs*3 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV67839850; called by mutect2, pindel, varscan2
- MTDH | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1333127142, COSV60343707; called by muse, mutect2, varscan2
- MYLK3 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs763522795, COSV67363940; called by muse, mutect2, varscan2
- NPM1 | c.408A>C p.L136F | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as COSV51556208; called by muse, mutect2, varscan2
- NRF1 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV56211786; called by muse, mutect2, varscan2
- NUP153 | c.3073G>A p.G1025S | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs940912694, COSV50448877; called by muse, mutect2, varscan2
- P2RY8 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs776454714, COSV67177190; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1630T>A p.F544I (on ENST00000259318 / NM_001136562.3; = p.F775I on NM_007203.5) | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV52175598; called by muse, mutect2, varscan2
- PLCL1 | c.2954C>T p.A985V | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs541983270, COSV70828209; called by muse, mutect2, varscan2
- POLI | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs146107490; called by mutect2, varscan2
- PRRG4 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV57672983; called by muse, mutect2, varscan2
- RHBDF2 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs868345572, COSV57420392; called by muse, mutect2, varscan2
- RTL9 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs200006075, COSV71825515; called by muse, mutect2
- SEPTIN11 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV53582073; called by muse, mutect2, varscan2
- SH2D3A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs767313865, COSV55585796; called by muse, mutect2, varscan2
- SLC26A8 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as rs772520541, COSV62885581, COSV62885594; called by muse, mutect2, varscan2
- SLC2A4 | c.726G>A p.K242= | Splice Region (SNP) | VAF 19/54 reads (35%) | catalogued as rs749829146, COSV50300809; called by muse, mutect2, varscan2
- SVEP1 | c.5934C>A p.N1978K | Missense Mutation (SNP) | VAF 108/332 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52838601; called by muse, varscan2
- SYT16 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368814141; called by muse, mutect2, varscan2
- TBC1D8 | c.1606G>C p.V536L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV65212004; called by muse, mutect2, varscan2
- TNS3 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs183514866; called by muse, mutect2, varscan2
- TRAV8-1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as rs569592065; called by muse, mutect2, varscan2
- TTN | c.83447C>T p.S27816F (on ENST00000591111; = p.S20392F on NM_003319.4) | Missense Mutation (SNP) | VAF 45/114 reads (39%) | PolyPhen benign (0.444); catalogued as COSV60015172; called by muse, mutect2, varscan2
- UCKL1 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62402727; called by muse, mutect2, varscan2
- ZC3HC1 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV61298078; called by muse, mutect2, varscan2
- ZNF883 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.204); catalogued as rs748826514, COSV71309032; called by muse, mutect2, varscan2
- FAT1 | c.6557dup p.Y2187Lfs*21 | Frame Shift Ins (INS) | VAF 69/209 reads (33%) | called by mutect2, pindel, varscan2
- ADCY4 | c.591C>T p.R197= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs929553540, COSV53475161; called by muse, mutect2, varscan2
- CCDC33 | c.567C>T p.N189= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs780750355, COSV58350987; called by muse, mutect2, varscan2
- GHSR | c.207G>A p.S69= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs995230051, COSV53838664, COSV53838892, COSV53839470; called by muse, mutect2, varscan2
- KCNJ12 | c.687C>T p.R229= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs569037483, COSV59163450; called by muse, mutect2, varscan2
- LRRIQ1 | c.3024C>T p.G1008= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs758936698, COSV67829876; called by muse, mutect2, varscan2
- MYOCD | c.2691G>A p.P897= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs149918258, COSV58503759; called by muse, mutect2, varscan2
- SAP130 | c.2766C>G p.V922= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV52096704; called by muse, mutect2, varscan2
- SLC6A20 | c.600G>A p.A200= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs780083357, COSV62071108; called by muse, mutect2, varscan2
- SULT1B1 | c.444T>C p.N148= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV60207480; called by muse, mutect2, varscan2
- TRIM49 | c.963C>T p.F321= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV61670700; called by muse, mutect2, varscan2
- TSHZ3 | c.2973C>T p.Y991= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs770720742, COSV53670088; called by muse, mutect2, varscan2
- TXNIP | c.996C>T p.P332= | Silent (SNP) | VAF 90/324 reads (28%) | catalogued as rs1553765925, COSV65220371, COSV65220693; called by muse, mutect2, varscan2
- ZNF10 | c.447A>G p.Q149= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV50212096; called by muse, mutect2, varscan2
- HMGN2P46 | n.809G>A | RNA (SNP) | VAF 15/71 reads (21%) | catalogued as rs368369764; called by muse, mutect2, varscan2
